Somatic mutation profile of tumor specimen 0DKGYT from CCDI case PBBYHR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 9.2 years (3,373 days).
Specimen 0DKGYT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70efea30-385c-4f65-b704-383b9a78a20c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKGX9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ea8bedc-362f-4263-9a50-0c8daa855e83

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Splice Region 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BOLA2-SMG1P6 | c.256-6C>T | Splice Region (SNP) | VAF 55/1328 reads (4%) | catalogued as rs1406713540; called by muse, mutect2
- PLEKHG3 | c.1591G>A p.A531T (on ENST00000394691; = p.A587T on NM_001308147.2) | Missense Mutation (SNP) | VAF 40/477 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs188437537; called by muse, mutect2
- RGSL1 | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV54260310; called by muse, mutect2
- XPOT | c.523A>T p.M175L | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- SHROOM2 | c.1905G>A p.Q635= | Silent (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2, varscan2
